Somatic mutation profile of tumor specimen TCGA-B0-5092-01A (aliquot TCGA-B0-5092-01A-01D-1421-08) from TCGA case TCGA-B0-5092, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 53.7 years (19,611 days).
Specimen TCGA-B0-5092-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40a8b824-cdfe-4a2a-ba38-091ba565bfe9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5092-11A (Solid Tissue Normal), aliquot TCGA-B0-5092-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9e74522-52a2-425c-b370-9cc789a53ca5

The open-access MAF lists 79 somatic variants for this specimen: 63 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 15, Nonsense Mutation 6, Frame Shift Del 4, Frame Shift Ins 2, Splice Region 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as rs387906849, CM119453, COSV56234336; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.757C>T p.Q253* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as rs776240891, COSV56230964; ClinVar: pathogenic; called by muse, mutect2
- AADACL4 | c.224T>C p.L75S | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs199989547, COSV66105940, COSV66106647; called by muse, mutect2
- ABCD3 | c.768A>G p.I256M | Missense Mutation (SNP) | VAF 32/206 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.065); catalogued as COSV59866823; called by muse, mutect2, varscan2
- ACSF2 | c.453G>C p.L151= | Splice Region (SNP) | VAF 6/39 reads (15%) | catalogued as COSV51973145; called by muse, mutect2, varscan2
- ACVR1C | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1187846687, COSV54647364; called by muse, mutect2
- AHNAK2 | c.6791A>G p.D2264G | Missense Mutation (SNP) | VAF 23/311 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1193526860, COSV60920015; called by muse, mutect2
- AKR1C1 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV66499395; called by muse, mutect2
- BIRC6 | c.2357C>A p.S786* | Nonsense Mutation (SNP) | VAF 23/176 reads (13%) | catalogued as COSV70201858; called by muse, mutect2, varscan2
- CBR1 | c.803T>G p.F268C | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51739355; called by muse, mutect2, varscan2
- CDKN2AIP | c.295A>G p.K99E | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56627465; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1340G>T p.G447V | Missense Mutation (SNP) | VAF 15/384 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65677569; called by muse, mutect2
- ELF2 | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.141); catalogued as COSV55494186; called by muse, mutect2
- EXOC2 | c.2320T>C p.S774P | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.147); catalogued as COSV57867930; called by muse, mutect2, varscan2
- FUBP3 | c.200A>T p.Q67L | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV60514930; called by muse, mutect2, varscan2
- GCNT2 | c.198A>T p.K66N | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.096); catalogued as COSV65457681; called by muse, mutect2, varscan2
- GINS3 | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV58919260, COSV58920023; called by muse, mutect2
- GPR63 | c.608G>T p.W203L | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57741482; called by muse, mutect2, varscan2
- GPRIN1 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs750799201, COSV56140976; called by muse, mutect2
- H3C12 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV58153258; called by muse, mutect2, varscan2
- HIPK3 | c.1776A>G p.A592= | Splice Region (SNP) | VAF 72/361 reads (20%) | catalogued as rs1206538070, COSV57563552; called by muse, mutect2, varscan2
- IRX1 | c.872C>A p.P291Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as COSV57360477; called by muse, mutect2
- IZUMO1R | c.425G>A p.C142Y (on ENST00000440961; = p.C149Y on NM_001199206.3) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60623020; called by muse, mutect2
- KBTBD2 | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 11/186 reads (6%) | catalogued as COSV58363831; called by muse, mutect2
- KIAA0895 | c.492G>T p.W164C (on ENST00000297063 / NM_001100425.2; = p.W113C on NM_015314.3) | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as COSV51711779; called by muse, mutect2, varscan2
- KLRC2 | c.84A>T p.K28N | Missense Mutation (SNP) | VAF 89/667 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as COSV101122763, COSV67900105; called by muse, mutect2, varscan2
- LRIG2 | c.124C>T p.L42F | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.136); catalogued as COSV63162826; called by muse, mutect2
- LRP1B | c.1939C>T p.P647S | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67241447; called by muse, mutect2
- MCTP2 | c.2469G>T p.W823C | Missense Mutation (SNP) | VAF 17/263 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63293462; called by muse, mutect2
- MUC16 | c.21568A>G p.S7190G | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV67476029; called by muse, mutect2, varscan2
- NCKAP1L | c.181A>T p.K61* | Nonsense Mutation (SNP) | VAF 18/163 reads (11%) | catalogued as COSV53208658; called by muse, mutect2, varscan2
- NDUFS4 | c.422A>C p.N141T | Missense Mutation (SNP) | VAF 8/202 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV57019170, COSV57019941; called by muse, mutect2
- NT5DC3 | c.1032G>C p.K344N | Missense Mutation (SNP) | VAF 67/483 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.21); catalogued as COSV67322121; called by muse, mutect2, varscan2
- PLOD3 | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56183837; called by muse, mutect2, varscan2
- PTAR1 | c.905T>A p.L302H | Missense Mutation (SNP) | VAF 76/404 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61207921, COSV61208861, COSV61209060; called by muse, mutect2, varscan2
- RAPGEF5 | c.1624T>A p.F542I (on ENST00000401957 / NM_001367602.2; = p.F845I on NM_012294.5) | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV59786445; called by muse, mutect2, varscan2
- RASAL1 | c.167A>T p.E56V | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55657396; called by muse, mutect2
- RELN | c.1603G>C p.A535P | Missense Mutation (SNP) | VAF 30/226 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV59013028; called by muse, mutect2, varscan2
- RGS3 | c.2953G>C p.E985Q (on ENST00000350696 / NM_001282923.2; = p.E704Q on NM_130795.4) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.917); catalogued as rs757485962, COSV59517958; called by muse, mutect2, varscan2
- SCAF4 | c.371A>G p.K124R | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs768757705, COSV54588949; called by muse, mutect2
- SF3B2 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59428840; called by muse, mutect2, varscan2
- SLC5A1 | c.1109T>C p.V370A | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs1379188562, COSV56686584; called by muse, mutect2, varscan2
- SLU7 | c.1003T>C p.Y335H | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.065); catalogued as COSV51788681; called by muse, mutect2
- SORCS2 | c.634A>T p.T212S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV61174276; called by muse, mutect2
- SUZ12 | c.667A>T p.K223* | Nonsense Mutation (SNP) | VAF 20/153 reads (13%) | catalogued as COSV59501251; called by muse, mutect2, varscan2
- TCF20 | c.5567A>T p.E1856V | Missense Mutation (SNP) | VAF 31/381 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59493418; called by muse, mutect2
- TNRC6A | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 61/322 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.453); catalogued as COSV59366768; called by muse, mutect2, varscan2
- TRIM23 | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.742); catalogued as rs779001000, COSV51549618; called by muse, mutect2, varscan2
- TSPAN6 | c.307G>T p.V103F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV65957393; called by muse, mutect2
- TSPAN6 | c.306G>T p.L102F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV65957398; called by muse, mutect2
- TTN | c.46810C>A p.P15604T (on ENST00000591111; = p.P8180T on NM_003319.4) | Missense Mutation (SNP) | VAF 38/352 reads (11%) | PolyPhen benign (0.068); catalogued as COSV60004375, COSV60157654; called by muse, mutect2, varscan2
- TUB | c.151A>T p.N51Y (on ENST00000299506 / NM_177972.3; = p.N106Y on NM_003320.4) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV55108711; called by muse, mutect2
- UBR1 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 19/393 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs375913511; called by muse, mutect2
- UGT2A3 | c.1342C>G p.H448D | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52360809; called by muse, mutect2, varscan2
- VHL | c.466_469dup p.T157Ifs*18 | Frame Shift Ins (INS) | VAF 5/46 reads (11%) | catalogued as COSV56542771; called by mutect2, pindel, varscan2
- WNK3 | c.1610A>G p.E537G | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV100671567, COSV63614791; called by muse, mutect2, varscan2
- ZC3H6 | c.910A>C p.K304Q | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59668964; called by muse, mutect2, varscan2
- ZNF165 | c.332A>T p.E111V | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV66102709; called by muse, mutect2, varscan2
- ATXN2L | c.3028del p.V1010Cfs*42 | Frame Shift Del (DEL) | VAF 23/149 reads (15%) | called by mutect2, pindel, varscan2
- CAMK1D | c.637dup p.I213Nfs*11 | Frame Shift Ins (INS) | VAF 25/171 reads (15%) | called by mutect2, pindel, varscan2
- EIF2AK4 | c.3401del p.L1134* | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- NEB | c.6608_6611del p.K2203Tfs*13 | Frame Shift Del (DEL) | VAF 23/198 reads (12%) | called by mutect2, pindel, varscan2
- PRRC2B | c.3251del p.N1084Mfs*86 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- CDADC1 | c.1098C>T p.Y366= | Silent (SNP) | VAF 96/537 reads (18%) | catalogued as COSV51912224; called by muse, mutect2, varscan2
- DDX6 | c.63G>A p.L21= | Silent (SNP) | VAF 38/190 reads (20%) | catalogued as COSV50589879; called by muse, mutect2, varscan2
- DPYD | c.2691G>A p.L897= | Silent (SNP) | VAF 57/235 reads (24%) | catalogued as COSV64603548; called by muse, mutect2, varscan2
- FAT4 | c.12462A>G p.A4154= | Silent (SNP) | VAF 23/272 reads (8%) | catalogued as rs1219270036, COSV100629063, COSV58693180; called by muse, mutect2
- FBLN1 | c.747G>A p.G249= | Silent (SNP) | VAF 24/224 reads (11%) | catalogued as COSV53049466; called by muse, mutect2
- GPATCH1 | c.2217C>T p.D739= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as rs370382787; called by muse, mutect2
- HPN | c.93C>T p.A31= | Silent (SNP) | VAF 7/202 reads (3%) | catalogued as COSV52884364; called by muse, mutect2
- PHLDA1 | c.534G>A p.G178= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV56997682; called by muse, mutect2, varscan2
- RBFOX1 | c.129C>T p.A43= | Silent (SNP) | VAF 28/213 reads (13%) | catalogued as rs776138625, COSV60965210; called by muse, mutect2, varscan2
- RP1L1 | c.2760G>A p.R920= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as COSV66756929; called by muse, mutect2, varscan2
- SELP | c.1986T>C p.F662= | Silent (SNP) | VAF 218/762 reads (29%) | catalogued as COSV55253965; called by muse, mutect2, varscan2
- SLX4 | c.2982C>A p.I994= | Silent (SNP) | VAF 34/191 reads (18%) | catalogued as COSV53563407; called by muse, mutect2, varscan2
- SORCS2 | c.633G>T p.P211= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs372434484, COSV61174257; called by muse, mutect2
- TP53 | c.291C>T p.V97= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV52907708, COSV53200016; called by muse, mutect2, varscan2
- UGGT1 | c.2940G>T p.P980= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV52137836; called by muse, mutect2, varscan2
- WNT16 | chr7:121325476 C>A | 5'Flank (SNP) | VAF 10/164 reads (6%) | catalogued as COSV55976436; called by muse, mutect2
